CPTAC case C3L-00999 — Floor of mouth — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Floor of mouth. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cf18a780-b1e9-4c67-ba29-0f561cf3d971

Demographics
Sex at birth: male; Race: white; Year of birth: 1961; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Floor of mouth, NOS; Site of resection or biopsy: Floor of mouth, NOS; Age at diagnosis: 56.2 years (20,513 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G1; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,137 days (3.1 years); Progression or recurrence: no; Days to last follow up: 1,137 days (3.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.2 cm (a second GDC size field records 2 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 17; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (4 entries)
- Days to follow up: 363 days; Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 818 days (2.2 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,137 days (3.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 446 days (1.2 years); Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,137 days (3.1 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.

Other clinical attributes
- Weight: 82 kg; Height: 176 cm; BMI: 26.47; Comorbidities: Pancreatitis; Pancreatitis onset year: 2017.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 36; Cigarettes per day: 20; Tobacco smoking onset year: 1981; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 41; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00999-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 39 days; Initial weight: 250 mg; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00999-21: Section location: Floor of Mouth; Percent tumor nuclei: 85; Percent necrosis: 3.
- Sample C3L-00999-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 39 days; Initial weight: 750 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00999-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 39 days; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00999-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 39 days; Method of sample procurement: Blood Draw.
